Somatic mutation profile of tumor specimen C3L-09062-01 (aliquot CPT0486930006) from CPTAC case C3L-09062, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-09062-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 005cd9fa-1a26-4321-8a5c-13e8e387a07e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09062-31 (Blood Derived Normal), aliquot CPT0486960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2f96e30-4759-4311-ad16-85e1047b81f8

The open-access MAF lists 7,292 somatic variants for this specimen: 4,700 protein-altering or splice-affecting, 2,331 silent, 261 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,295, Silent 2,331, Nonsense Mutation 266, Intron 158, Splice Region 60, Splice Site 34, 3'UTR 34, 5'Flank 26, Frame Shift Del 22, 5'UTR 15, RNA 14, 3'Flank 14.

Variants (750 of 7,292; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB6 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 103/453 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764893806, CM1211185, COSV54693138; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADNP | c.2187dup p.R730Tfs*5 | Frame Shift Ins (INS) | VAF 94/345 reads (27%) | catalogued as rs1555809987; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ARX | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 103/477 reads (22%) | catalogued as rs587783182, COSV66874983, COSV66875600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A3 | c.2302G>A p.G768S (on ENST00000545399 / NM_001256214.2; = p.G755S on NM_152296.5) | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557052809, CM127596, CM127804; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLRN1 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 181/433 reads (42%) | catalogued as rs878853379; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL6A3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 165/517 reads (32%) | catalogued as rs121434554, CM021076, COSV55086452; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC1H1 | c.4532C>T p.P1511L | Missense Mutation (SNP) | VAF 90/355 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327664377, COSV64134818; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 88/295 reads (30%) | catalogued as rs794727215; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GCK | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 112/583 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs193922336, CM022210, COSV60786010; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIT | c.2465A>T p.N822I | Missense Mutation (SNP) | VAF 98/201 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993022333, CM114977, COSV55406976, COSV55413741; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 97/282 reads (34%) | catalogued as rs1018100729, CM053943, COSV70339501, COSV70351786; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LAMA3 | c.7489C>T p.Q2497* (on ENST00000313654 / NM_198129.4; = p.Q888* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 59/258 reads (23%) | catalogued as rs1555737779; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRRK2 | c.3342A>G p.L1114= | Silent (SNP) | VAF 67/248 reads (27%) | catalogued as rs35808389, CS053469, COSV54142394; ClinVar: likely benign / pathogenic; called by muse, mutect2, varscan2
- PAX6 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 114/348 reads (33%) | catalogued as rs1131692300, CM068279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC6A3 | c.671T>C p.L224P | Missense Mutation (SNP) | VAF 225/458 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs431905515, CM108191; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 97/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TRPV6 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 136/485 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1327315227, COSV63891066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as rs373946729; called by muse, mutect2, varscan2
- A2ML1 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366018648; called by muse, varscan2
- A2ML1 | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751048962; called by muse, mutect2, varscan2
- ABCA12 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 81/239 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV99788308, COSV99788845; called by muse, mutect2, varscan2
- ABCA4 | c.6750A>T p.K2250N | Missense Mutation (SNP) | VAF 97/299 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as CD013129; called by muse, mutect2, varscan2
- ABCA6 | c.4625C>T p.S1542F | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as rs775924900; called by muse, mutect2, varscan2
- ABCA8 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 91/738 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs370110491; called by muse, mutect2, varscan2
- ABCA9 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 103/474 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.028); catalogued as rs1440139182; called by muse, mutect2, varscan2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 247/602 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABCC3 | c.3841G>A p.E1281K | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs754026312; called by muse, mutect2, varscan2
- ABCC4 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs781506182; called by muse, mutect2, varscan2
- ABCC9 | c.4061C>T p.S1354L | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53972591; called by muse, mutect2, varscan2
- ABCD2 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58051188; called by muse, varscan2
- ABCD2 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58055263; called by muse, varscan2
- ABCF3 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 122/345 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs924023051; called by muse, mutect2, varscan2
- ABCG1 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.934); catalogued as COSV59211139; called by muse, mutect2, varscan2
- AC005833.1 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious, low confidence (0.02); catalogued as rs1395176251; called by muse, mutect2, varscan2
- AC006059.2 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 109/478 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1416999379; called by muse, mutect2, varscan2
- AC126283.2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1355835737, COSV67099135; called by muse, mutect2, varscan2
- AC127029.3 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 113/790 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs766570969; called by muse, mutect2, varscan2
- ACAN | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 155/524 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV61359834; called by muse, mutect2, varscan2
- ACAP3 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 177/430 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs989999025, COSV57639633; called by muse, mutect2, varscan2
- ACOT6 | c.16A>G p.K6E | Missense Mutation (SNP) | VAF 108/390 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs759899042; called by muse, mutect2, varscan2
- ACOX2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 229/494 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs1311486181; called by muse, mutect2, varscan2
- ACSM2A | c.794G>A p.W265* (on ENST00000219054; = p.W186* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 91/375 reads (24%) | catalogued as rs200963964, COSV54583589; called by muse, mutect2, varscan2
- ACSM2B | c.594A>G p.L198= | Splice Region (SNP) | VAF 50/205 reads (24%) | catalogued as rs766763821; called by muse, mutect2, varscan2
- ACSM4 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 133/481 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68067061; called by muse, mutect2, varscan2
- ACSS3 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 145/496 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs747840747, COSV54089221; called by muse, mutect2, varscan2
- ACTG2 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 123/437 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV61827941; called by muse, mutect2, varscan2
- ACTR8 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 76/354 reads (21%) | catalogued as COSV99213896; called by muse, mutect2, varscan2
- ADAM18 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 73/243 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV55847835; called by muse, mutect2, varscan2
- ADAM19 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 102/575 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV57424244; called by muse, varscan2
- ADAM22 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs370014529, COSV55969068; called by muse, varscan2
- ADAM28 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 93/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303422157, COSV56099428, COSV56099824; called by muse, mutect2, varscan2
- ADAM29 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 80/409 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63660843, COSV63663413; called by muse, mutect2, varscan2
- ADAM30 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 105/382 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV65560479; called by muse, mutect2, varscan2
- ADAM30 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.496); catalogued as rs1276029798; called by muse, mutect2, varscan2
- ADAM7 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.759); catalogued as COSV99442678; called by muse, mutect2, varscan2
- ADAMDEC1 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs754566400; called by muse, mutect2, varscan2
- ADAMDEC1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 91/328 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as rs753899251, COSV56474101; called by muse, mutect2, varscan2
- ADAMTS10 | c.3184C>T p.P1062S | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1555736418; called by muse, varscan2
- ADAMTS10 | c.2350C>T p.Q784* | Nonsense Mutation (SNP) | VAF 103/464 reads (22%) | catalogued as rs886041105; called by muse, mutect2, varscan2
- ADAMTS10 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 120/513 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.803); catalogued as rs782396164, COSV54352584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.1741G>A p.G581R | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51424671; called by muse, mutect2, varscan2
- ADAMTS2 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 128/353 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.702); catalogued as rs746024135; called by muse, mutect2, varscan2
- ADAMTS2 | c.2159G>A p.S720N | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV52376182; called by muse, mutect2, varscan2
- ADAMTS2 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 206/422 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.029); catalogued as rs1473795363, COSV52372953; called by muse, mutect2
- ADAMTS2 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 75/478 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866154925; called by muse, mutect2, varscan2
- ADAMTS5 | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 83/290 reads (29%) | catalogued as rs752275922, COSV53179920; called by muse, mutect2, varscan2
- ADAMTS5 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 102/536 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV53177515; called by muse, mutect2, varscan2
- ADAMTS6 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 176/363 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as rs753648478; called by muse, mutect2, varscan2
- ADAMTS7 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 118/422 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as rs752052126; called by muse, varscan2
- ADAMTS8 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 154/418 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1298357265, COSV57295102; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs779193184; called by mutect2, varscan2
- ADAMTSL3 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54456840; called by muse, mutect2, varscan2
- ADAP1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 88/462 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs769564217; called by muse, mutect2, varscan2
- ADAP2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 112/377 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as COSV100437398; called by muse, varscan2
- ADAP2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV58295717; called by muse, mutect2, varscan2
- ADCY1 | c.2821A>G p.K941E | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs755500831; called by muse, mutect2, varscan2
- ADCY10 | c.2967G>A p.M989I | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1409674308; called by muse, mutect2, varscan2
- ADCY7 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 70/346 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1299490235; called by muse, mutect2, varscan2
- ADCY8 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53919132; called by muse, mutect2, varscan2
- ADCY8 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 123/461 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781040718, COSV53895055; called by muse, mutect2, varscan2
- ADD2 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 163/554 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs781794877, COSV52456514; called by muse, mutect2, varscan2
- ADD2 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 122/357 reads (34%) | catalogued as COSV100036774, COSV52455725; called by muse, mutect2, varscan2
- ADGRB1 | c.4153G>A p.E1385K | Missense Mutation (SNP) | VAF 94/364 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1019734108; called by muse, varscan2
- ADGRB2 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 181/357 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747171444, COSV57074087; called by muse, mutect2, varscan2
- ADGRE3 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 56/249 reads (22%) | catalogued as rs149254238, COSV99506422; called by muse, mutect2, varscan2
- ADGRF4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 105/351 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs377029853; called by muse, mutect2, varscan2
- ADGRF5 | c.1825C>T p.L609F | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777345799; called by muse, mutect2, varscan2
- ADGRG4 | c.4877C>T p.S1626F | Missense Mutation (SNP) | VAF 114/405 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99794690; called by muse, mutect2, varscan2
- ADGRG4 | c.9082G>A p.G3028R | Missense Mutation (SNP) | VAF 100/450 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99795929; called by muse, mutect2
- ADGRG5 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 133/442 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746326136; called by mutect2, varscan2
- ADGRG7 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs373804273, COSV56297862; called by muse, mutect2, varscan2
- ADGRL2 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as rs1167044032; called by muse, mutect2, varscan2
- ADGRV1 | c.9199C>T p.L3067F | Missense Mutation (SNP) | VAF 106/223 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV101316453; called by muse, mutect2, varscan2
- ADH4 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as rs139053416, COSV55500780; called by muse, mutect2, varscan2
- ADNP2 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 147/612 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100081105; called by muse, mutect2
- AFAP1L2 | c.1846C>T p.Q616* | Nonsense Mutation (SNP) | VAF 196/504 reads (39%) | catalogued as COSV58418561; called by muse, mutect2, varscan2
- AFF3 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 112/427 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs761392199; called by muse, mutect2, varscan2
- AGAP2 | c.2987C>T p.T996I (on ENST00000547588 / NM_001122772.2; = p.T640I on NM_014770.4) | Missense Mutation (SNP) | VAF 183/646 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs1162962655, COSV57730511; called by muse, mutect2, varscan2
- AGAP4 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1310025901; called by muse, mutect2, varscan2
- AGAP9 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 148/1137 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.531); catalogued as COSV62225481; called by muse, varscan2
- AGBL1 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 114/464 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as rs201541206; called by muse, mutect2, varscan2
- AGL | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99649860; called by muse, mutect2, varscan2
- AGMO | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs761412430; called by muse, mutect2, varscan2
- AGO1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 133/267 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371043471; called by muse, mutect2, varscan2
- AGO1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs758951181, COSV64594852; called by muse, varscan2
- AHCYL2 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs1363947128; called by muse, mutect2, varscan2
- AHI1 | c.2116C>T p.H706Y | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99662212; called by muse, mutect2, varscan2
- AHNAK2 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 146/574 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100316036; called by muse, mutect2, varscan2
- AIM2 | c.1021A>T p.K341* | Nonsense Mutation (SNP) | VAF 116/313 reads (37%) | catalogued as COSV63701567; called by muse, mutect2, varscan2
- AK9 | c.5269C>T p.R1757C | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs775310575, COSV69851307; called by muse, mutect2, varscan2
- AKAP1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 144/637 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs754433141, COSV58471455; called by muse, mutect2, varscan2
- AKAP3 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 112/398 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV57417623; called by muse, mutect2, varscan2
- AKAP6 | c.6184G>A p.E2062K | Missense Mutation (SNP) | VAF 89/399 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55206082; called by muse, mutect2, varscan2
- AKR1D1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs148732404; ClinVar: uncertain significance; called by muse, varscan2
- ALB | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV55735785; called by muse, mutect2, varscan2
- ALB | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 117/388 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV55742933; called by muse, mutect2, varscan2
- ALB | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 98/317 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV55738239; called by muse, mutect2, varscan2
- ALCAM | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201545016; called by muse, mutect2, varscan2
- ALG1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 157/300 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as CM137864; called by muse, mutect2, varscan2
- ALMS1 | c.6140C>T p.S2047F | Missense Mutation (SNP) | VAF 117/381 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); catalogued as rs749618073; called by muse, mutect2, varscan2
- ALOX5 | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 74/293 reads (25%) | catalogued as COSV65552588; called by muse, mutect2, varscan2
- ALOX5 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV65551793; called by muse, varscan2
- ALPK2 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 155/499 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV64494797; called by muse, mutect2, varscan2
- AMER3 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 102/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58464938; called by muse, mutect2, varscan2
- AMER3 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 152/552 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV58465723; called by muse, mutect2, varscan2
- AMFR | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 68/311 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs779952471, COSV51922629; called by muse, mutect2, varscan2
- AMHR2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 71/337 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); catalogued as rs1182853719; called by muse, mutect2, varscan2
- AMPD3 | c.734G>A p.S245N (on ENST00000396553 / NM_001025389.2; = p.S254N on NM_000480.3) | Missense Mutation (SNP) | VAF 105/460 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1258358377, COSV101158073; called by muse, mutect2, varscan2
- ANAPC1 | c.4972C>T p.P1658S | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs1299654211, COSV61976746; called by muse, mutect2, varscan2
- ANK1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs752903517, COSV55887962; called by muse, mutect2, varscan2
- ANK3 | c.9982C>T p.P3328S | Missense Mutation (SNP) | VAF 90/369 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs148029765, COSV55060820; called by muse, mutect2, varscan2
- ANK3 | c.8809G>A p.E2937K | Missense Mutation (SNP) | VAF 90/362 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV55066722; called by muse, mutect2, varscan2
- ANK3 | c.6529G>A p.D2177N | Missense Mutation (SNP) | VAF 95/408 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55074819; called by muse, mutect2, varscan2
- ANK3 | c.4102G>A p.D1368N (on ENST00000280772 / NM_001320874.2; = p.D502N on NM_001149.3) | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99781462; called by muse, mutect2, varscan2
- ANKFN1 | c.1628G>A p.G543E | Missense Mutation (SNP) | VAF 88/331 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568024401; called by muse, varscan2
- ANKRD11 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 96/404 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56355666; called by muse, mutect2, varscan2
- ANKRD12 | c.3713C>T p.S1238L | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV100042052; called by muse, mutect2, varscan2
- ANKRD18A | c.1987T>C p.F663L | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.827); catalogued as rs910270306; called by muse, mutect2, varscan2
- ANKRD18B | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.316); catalogued as rs1369919206; called by muse, mutect2, varscan2
- ANKRD24 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs1480503769; called by muse, mutect2, varscan2
- ANKRD24 | c.1272G>A p.G424= | Splice Region (SNP) | VAF 68/305 reads (22%) | catalogued as rs1446355840; called by muse, mutect2, varscan2
- ANKRD30A | c.1235G>A p.G412E (on ENST00000611781; = p.G356E on NM_052997.2) | Missense Mutation (SNP) | VAF 108/481 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1229987200, COSV64605641; called by muse, mutect2, varscan2
- ANKRD30A | c.1543G>A p.E515K (on ENST00000611781; = p.E459K on NM_052997.2) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.899); catalogued as rs1436421437; called by muse, mutect2, varscan2
- ANKRD30A | c.3184G>A p.E1062K (on ENST00000611781; = p.E1006K on NM_052997.2) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100654384; called by muse, mutect2, varscan2
- ANKRD6 | c.2176G>A p.E726K (on ENST00000339746 / NM_001242809.2; = p.E721K on NM_014942.4) | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as rs1245525404; called by muse, mutect2, varscan2
- ANO2 | c.692C>T p.S231L (on ENST00000356134 / NM_001278597.3; = p.S235L on NM_001278596.3) | Missense Mutation (SNP) | VAF 130/461 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs772006493, COSV59012074, COSV59032011; called by muse, mutect2, varscan2
- ANO4 | c.2443G>A p.G815R (on ENST00000392977 / NM_001286615.2; = p.G780R on NM_178826.4) | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV54613050; called by muse, mutect2, varscan2
- ANTXR1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 111/384 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV58023545; called by muse, mutect2, varscan2
- AOX1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs767296439; called by muse, mutect2, varscan2
- APCDD1L | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 104/440 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs768052233, COSV100953922; called by muse, varscan2
- APCDD1L | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 84/312 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs373839055; called by muse, varscan2
- APCS | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99661246; called by muse, mutect2, varscan2
- APLNR | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57243760; called by muse, varscan2
- APOB | c.10508C>T p.S3503L | Missense Mutation (SNP) | VAF 158/515 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs375284245, CM088504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.7937C>T p.S2646F | Missense Mutation (SNP) | VAF 126/437 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV51925517; called by muse, mutect2, varscan2
- APOB | c.4173G>A p.M1391I | Missense Mutation (SNP) | VAF 113/448 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV51936540; called by muse, varscan2
- APOBEC4 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 128/388 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1206308615; called by muse, mutect2, varscan2
- APOBR | c.3025C>T p.R1009C (on ENST00000431282; = p.R1018C on NM_018690.4) | Missense Mutation (SNP) | VAF 155/543 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs528190355, COSV60489033; called by muse, mutect2, varscan2
- APOL5 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 103/347 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs750413929, COSV50768088; called by muse, mutect2, varscan2
- AQP8 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 107/412 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.367); catalogued as COSV54844347; called by muse, mutect2, varscan2
- AR | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 124/386 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65955976; called by muse, mutect2, varscan2
- ARAP2 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141950924, COSV58293960; called by muse, mutect2, varscan2
- ARAP2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1014608445, COSV58293695; called by muse, mutect2, varscan2
- ARFGEF3 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 132/461 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs755452517, COSV52454593; called by muse, mutect2, varscan2
- ARFGEF3 | c.5953G>A p.D1985N | Missense Mutation (SNP) | VAF 116/518 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.02); catalogued as rs771574519; called by muse, mutect2, varscan2
- ARHGAP22 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 191/717 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1187388407; called by muse, mutect2, varscan2
- ARHGAP26 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs778398220; called by muse, mutect2, varscan2
- ARHGAP27 | c.1845C>T p.S615= (on ENST00000428638 / NM_001282290.1; = p.S274= on NM_199282.3) | Splice Region (SNP) | VAF 88/366 reads (24%) | catalogued as rs1465333724; called by muse, varscan2
- ARHGAP29 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 105/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1168172960; called by muse, mutect2, varscan2
- ARHGAP32 | c.1778C>T p.P593L (on ENST00000310343 / NM_001378025.1; = p.P244L on NM_014715.4) | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100087295; called by muse, mutect2, varscan2
- ARHGAP32 | c.1777C>T p.P593S (on ENST00000310343 / NM_001378025.1; = p.P244S on NM_014715.4) | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1280146684; called by muse, mutect2, varscan2
- ARHGAP44 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs267604747, COSV52389603, COSV52405088; called by muse, varscan2
- ARHGAP44 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99311002; called by muse, mutect2, varscan2
- ARHGAP5 | c.2398C>T p.L800F | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs776464378, COSV61539523; called by muse, mutect2, varscan2
- ARHGEF10 | c.1160C>T p.S387F (on ENST00000398564; = p.S362F on NM_014629.4) | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV50643245; called by muse, mutect2, varscan2
- ARHGEF17 | c.4703C>T p.P1568L | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1253006021; called by muse, mutect2, varscan2
- ARHGEF2 | c.2953G>A p.E985K (on ENST00000361247 / NM_001162383.2; = p.E957K on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/378 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs921566752; called by muse, mutect2, varscan2
- ARHGEF4 | c.820G>A p.G274R | Missense Mutation (SNP) | VAF 218/667 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs758346864; called by muse, mutect2, varscan2
- ARHGEF5 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 81/710 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs746398217; called by muse, mutect2, varscan2
- ARHGEF5 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99282795; called by muse, varscan2
- ARID1A | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 189/401 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100250784; called by muse, mutect2, varscan2
- ARID1A | c.4582C>T p.R1528* | Nonsense Mutation (SNP) | VAF 240/451 reads (53%) | catalogued as COSV100251965, COSV61372105; called by muse, mutect2, varscan2
- ARMCX2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 165/564 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs781783235, COSV57529674; called by muse, mutect2, varscan2
- ARMH1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV62637139; called by muse, mutect2, varscan2
- ARMH4 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 130/456 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs769362182, COSV50762374, COSV50766343; called by muse, mutect2, varscan2
- ARPP21 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 89/476 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs535388566, COSV51802472; called by muse, mutect2, varscan2
- ARSD | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 171/577 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as rs752439282; called by muse, mutect2, varscan2
- ARSJ | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 90/282 reads (32%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV59536688; called by muse, mutect2, varscan2
- ART1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51702739; called by muse, mutect2, varscan2
- ASH1L | c.3938G>A p.R1313Q | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.921); catalogued as rs369029306; called by muse, mutect2, varscan2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 134/502 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by muse, mutect2, varscan2
- ASIC5 | c.1409A>G p.N470S | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs376534501; called by muse, mutect2, varscan2
- ASIC5 | c.1236G>A p.R412= | Splice Region (SNP) | VAF 42/150 reads (28%) | catalogued as COSV101611149; called by muse, mutect2, varscan2
- ASIC5 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 133/402 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs149268529; called by muse, mutect2, varscan2
- ASPM | c.3424C>T p.R1142C | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775031676; called by muse, mutect2, varscan2
- ASPN | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 21/162 reads (13%) | catalogued as COSV65016015; called by muse, varscan2
- ASPN | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs867443422; called by muse, varscan2
- ASTN1 | c.3648G>A p.R1216= | Splice Region (SNP) | VAF 58/251 reads (23%) | catalogued as COSV62490720; called by muse, mutect2, varscan2
- ASXL3 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 107/455 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.618); catalogued as COSV52482683; called by muse, mutect2, varscan2
- ATF7IP2 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 140/246 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100202693; called by muse, mutect2, varscan2
- ATG2B | c.4957C>T p.R1653C | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs773625847, COSV55890358; called by muse, mutect2, varscan2
- ATG4A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.031); catalogued as rs1338736044, COSV57874853; called by muse, mutect2, varscan2
- ATP10A | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766902642; called by muse, mutect2, varscan2
- ATP10B | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 101/555 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs1444200377; called by muse, mutect2, varscan2
- ATP12A | c.1674G>A p.M558I | Missense Mutation (SNP) | VAF 106/456 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV54523296; called by muse, varscan2
- ATP13A4 | c.3176G>A p.G1059E | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61328945; called by muse, mutect2, varscan2
- ATP13A4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV99795341; called by muse, mutect2, varscan2
- ATP1A2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63405819; called by muse, mutect2, varscan2
- ATP2A3 | c.1767G>A p.T589= | Splice Region (SNP) | VAF 96/330 reads (29%) | catalogued as rs763834422; called by muse, mutect2, varscan2
- ATP2A3 | c.1704C>G p.D568E | Missense Mutation (SNP) | VAF 135/498 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as COSV59226275, COSV99988912; called by muse, mutect2, varscan2
- ATP2B2 | c.2053G>A p.E685K (on ENST00000352432; = p.E651K on NM_001683.5) | Missense Mutation (SNP) | VAF 269/609 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs752661102, COSV59493351; called by muse, mutect2, varscan2
- ATP2B4 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1292104307, COSV58176951; called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.7T>G p.S3A | Missense Mutation (SNP) | VAF 154/499 reads (31%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.986); catalogued as rs763821064; called by muse, mutect2, varscan2
- ATP6AP2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 81/378 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs138458908; called by muse, mutect2, varscan2
- ATP8A1 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as rs1318545040, COSV100044557; called by muse, mutect2, varscan2
- ATP8B4 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs866255846, COSV52712173; called by muse, varscan2
- ATP8B4 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 81/310 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs569305697, COSV52725371; called by muse, varscan2
- ATP9A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 104/445 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756587295, COSV58762895, COSV58762969; called by muse, mutect2, varscan2
- ATRN | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.175); catalogued as rs1393625169; called by muse, mutect2, varscan2
- AUTS2 | c.3284T>G p.L1095R | Missense Mutation (SNP) | VAF 140/535 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs930577652; called by muse, mutect2, varscan2
- AUTS2 | c.3455G>T p.R1152L | Missense Mutation (SNP) | VAF 168/692 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100716331; called by muse, varscan2
- AWAT1 | c.255G>A p.T85= | Splice Region (SNP) | VAF 83/357 reads (23%) | catalogued as rs372091173; called by muse, varscan2
- AWAT1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV65739126; called by muse, mutect2, varscan2
- AXDND1 | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62650422; called by muse, mutect2, varscan2
- AXL | c.2452G>A p.E818K (on ENST00000301178 / NM_021913.5; = p.E809K on NM_001699.6) | Missense Mutation (SNP) | VAF 107/425 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763066660, COSV56564019; called by muse, mutect2, varscan2
- B3GALNT1 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 132/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1275651314; called by muse, mutect2, varscan2
- B3GALT1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 116/449 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267598991, COSV100002797; called by muse, mutect2, varscan2
- BACH2 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1421299014; called by muse, mutect2, varscan2
- BACH2 | c.2075G>A p.R692K | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99998102; called by muse, mutect2, varscan2
- BACH2 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100000956; called by muse, mutect2, varscan2
- BAG6 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 278/965 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs916595467; called by muse, mutect2, varscan2
- BAIAP2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 136/842 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.909); catalogued as COSV58339385; called by muse, varscan2
- BANP | c.1022C>T p.S341F (on ENST00000286122; = p.S310F on NM_017869.4) | Missense Mutation (SNP) | VAF 84/381 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99621679; called by muse, mutect2, varscan2
- BARX2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99858558; called by muse, mutect2, varscan2
- BBS10 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs1056258312, COSV101283394; called by muse, mutect2, varscan2
- BCAT1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs866415368; called by muse, mutect2, varscan2
- BCL11A | c.1170G>A p.M390I (on ENST00000335712 / NM_001365609.1; = p.M424I on NM_018014.4) | Missense Mutation (SNP) | VAF 174/619 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV59633523; called by muse, mutect2, varscan2
- BCL11A | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 143/471 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867919413, COSV59629057; called by muse, mutect2, varscan2
- BCL7A | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 118/464 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99947324; called by muse, mutect2
- BCLAF1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs781078230, COSV62141813; called by muse, mutect2, varscan2
- BCOR | c.5194G>A p.E1732K (on ENST00000378444 / NM_001123385.2; = p.E1698K on NM_017745.6) | Missense Mutation (SNP) | VAF 165/595 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs1437936868, COSV100653058, COSV60700979; called by muse, mutect2, varscan2
- BCORL1 | c.4699G>A p.E1567K | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV54394639; called by muse, mutect2, varscan2
- BEND5 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65718853; called by muse, mutect2, varscan2
- BEST2 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50377437; called by muse, mutect2, varscan2
- BEX5 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 150/560 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs782360844; called by muse, varscan2
- BIRC3 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 434/785 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs1173728754, COSV99074338; called by muse, mutect2, varscan2
- BMP10 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 129/467 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1558686747; called by muse, mutect2, varscan2
- BMPER | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 114/518 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV51831223; called by muse, mutect2, varscan2
- BOD1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 209/494 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53633087; called by muse, mutect2, varscan2
- BPI | c.1021C>T p.P341S (on ENST00000262865; = p.P337S on NM_001725.3) | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867317791, COSV53407177; called by muse, mutect2, varscan2
- BPIFB6 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs200655488; called by muse, varscan2
- BPIFC | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs78469100, COSV55910676; called by muse, mutect2, varscan2
- BPTF | c.7445C>T p.P2482L | Missense Mutation (SNP) | VAF 146/825 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.205); catalogued as COSV58830685; called by muse, mutect2, varscan2
- BRD1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 138/479 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs775794055; called by muse, mutect2, varscan2
- BRINP3 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 135/414 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs267598249, COSV66519090; called by muse, mutect2, varscan2
- BRIP1 | c.3716C>T p.S1239F | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs929857537, CM1512704, COSV52009886; called by muse, varscan2
- BRWD1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV100313404; called by muse, mutect2, varscan2
- BSND | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 94/380 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760023611, COSV64870346; called by muse, mutect2, varscan2
- BTK | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 77/265 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as CM155442, COSV58118558, COSV58123708; called by muse, mutect2, varscan2
- BTN3A1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 125/428 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs374921833, COSV50024493; called by muse, mutect2, varscan2
- C10orf67 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779268711; called by muse, mutect2, varscan2
- C10orf71 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV60505164; called by muse, mutect2, varscan2
- C10orf71 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 92/402 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV60513029; called by muse, mutect2, varscan2
- C12orf40 | c.1642C>T p.H548Y | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); catalogued as rs952381237; called by muse, mutect2, varscan2
- C12orf50 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 118/462 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779858673; called by muse, mutect2, varscan2
- C16orf71 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 246/437 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs377114180; called by muse, mutect2, varscan2
- C17orf97 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 111/429 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.511); catalogued as rs782425212; called by muse, mutect2, varscan2
- C19orf38 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 101/320 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs267605279, COSV67318711; called by muse, mutect2, varscan2
- C1QL4 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs570885459; called by muse, mutect2, varscan2
- C1orf158 | c.238A>T p.K80* | Nonsense Mutation (SNP) | VAF 123/263 reads (47%) | catalogued as COSV55346120; called by muse, mutect2, varscan2
- C1orf68 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 106/512 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.857); catalogued as rs1382968363, COSV64224445; called by muse, varscan2
- C2orf78 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 163/547 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs766819861, COSV68519592; called by muse, mutect2, varscan2
- C4BPA | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 94/334 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV65537199, COSV65537328; called by muse, mutect2, varscan2
- C4orf54 | c.3485G>A p.R1162K | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs978626471; called by muse, varscan2
- C5orf58 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 73/471 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.011); catalogued as rs1018915263; called by muse, mutect2, varscan2
- C6 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 125/273 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs774726786, COSV54706420; called by muse, mutect2, varscan2
- C6orf132 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 100/490 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV59374919; called by muse, mutect2, varscan2
- C6orf201 | c.285-1G>A p.X95_splice | Splice Site (SNP) | VAF 70/188 reads (37%) | catalogued as rs866704510; called by mutect2, varscan2
- C6orf58 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV61666512; called by muse, mutect2, varscan2
- C7 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 243/438 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57476307; called by muse, mutect2, varscan2
- C9orf131 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs763688937; called by muse, mutect2, varscan2
- C9orf131 | c.2972G>A p.R991K | Missense Mutation (SNP) | VAF 138/414 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs776843029; called by muse, mutect2, varscan2
- CA12 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 86/338 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1450952781; called by muse, mutect2, varscan2
- CA4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 85/549 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV56282216; called by muse, varscan2
- CA4 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 66/395 reads (17%) | catalogued as COSV99039722; called by muse, varscan2
- CAB39L | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs776732990; called by muse, mutect2, varscan2
- CABIN1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1384577517; called by muse, mutect2, varscan2
- CABP1 | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 113/518 reads (22%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.005); catalogued as rs1197727391; called by muse, mutect2, varscan2
- CABP5 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 77/343 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99506768; called by muse, mutect2, varscan2
- CABS1 | c.649A>T p.I217F | Missense Mutation (SNP) | VAF 100/309 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1338906017; called by muse, mutect2, varscan2
- CACNA1A | c.6270G>A p.M2090I | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100803153; called by muse, mutect2, varscan2
- CACNA1B | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 96/723 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as rs773700895; called by muse, mutect2, varscan2
- CACNA1F | c.4008G>A p.M1336I | Missense Mutation (SNP) | VAF 143/486 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV59907208; called by muse, mutect2, varscan2
- CACNA1G | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 126/497 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.201); catalogued as rs768241607; called by muse, mutect2, varscan2
- CACNA1I | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 154/624 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as rs1219721468, COSV60800523; called by muse, varscan2
- CACNA1S | c.4703C>T p.P1568L | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1377438279, COSV100755149, COSV62944340; called by muse, varscan2
- CACNA1S | c.3715C>T p.R1239C | Missense Mutation (SNP) | VAF 160/425 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28930069, CM940216; called by muse, mutect2, varscan2
- CACNA2D2 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 132/587 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56562084; called by muse, mutect2, varscan2
- CACNA2D2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 121/425 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs559004773; called by muse, mutect2, varscan2
- CACNA2D3 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 217/526 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as COSV55535714; called by muse, mutect2, varscan2
- CACNA2D4 | c.2244C>T p.S748= | Splice Region (SNP) | VAF 78/304 reads (26%) | catalogued as rs771296834; called by muse, varscan2
- CACNG1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 100/558 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.385); catalogued as rs760216442, COSV56826298, COSV56827091; called by muse, mutect2, varscan2
- CACNG3 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 109/424 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV50086695; called by muse, varscan2
- CACNG3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 122/392 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs868820485, COSV50063824; called by muse, varscan2
- CACNG4 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 56/540 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50924562; called by muse, mutect2
- CAD | c.6598C>T p.R2200C | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466458693; called by muse, mutect2, varscan2
- CADM2 | c.755G>A p.G252E (on ENST00000407528 / NM_001167674.2; = p.G254E on NM_153184.4) | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67357577; called by muse, mutect2, varscan2
- CADM2 | c.949C>T p.P317S (on ENST00000407528 / NM_001167674.2; = p.P319S on NM_153184.4) | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV67359479; called by muse, mutect2, varscan2
- CAMK1G | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV50520817; called by muse, mutect2, varscan2
- CAMKK2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 109/411 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV61217103; called by muse, mutect2, varscan2
- CAMSAP3 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 106/358 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1438780762; called by muse, mutect2, varscan2
- CAPN15 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 154/302 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417919392, COSV99562289; called by muse, mutect2, varscan2
- CAPN3 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1237444643, CM051865; called by muse, mutect2, varscan2
- CAPN6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 137/544 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs766454026, COSV60693679; called by muse, mutect2, varscan2
- CARD11 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as COSV104423172, COSV99067178; called by muse, varscan2
- CARMIL2 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs770638604; called by muse, varscan2
- CARMIL3 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 107/417 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs867486596, COSV57728379; called by muse, mutect2, varscan2
- CARMIL3 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 97/403 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs909993517, COSV57728931; called by muse, mutect2, varscan2
- CASP10 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53777058; called by muse, mutect2, varscan2
- CASP4 | c.122A>T p.E41V | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV101274253; called by muse, mutect2, varscan2
- CASR | c.2707G>A p.D903N (on ENST00000490131; = p.D980N on NM_000388.4) | Missense Mutation (SNP) | VAF 162/417 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs1268294939, COSV56138907; called by muse, mutect2, varscan2
- CATSPER2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58660523; called by muse, mutect2, varscan2
- CATSPERB | c.2786C>T p.S929L | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56429745; called by muse, mutect2, varscan2
- CATSPERD | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 103/383 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs556651366; called by muse, mutect2, varscan2
- CBLL2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 138/535 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV60368825; called by muse, mutect2, varscan2
- CC2D1A | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 112/432 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754426299, COSV100528282; called by muse, mutect2, varscan2
- CCBE1 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs763623450, COSV101232816; called by muse, mutect2, varscan2
- CCBE1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 129/448 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1216440169, COSV101232798, COSV67949532; called by muse, mutect2, varscan2
- CCDC102B | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.146); catalogued as COSV60143355; called by muse, mutect2, varscan2
- CCDC102B | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 121/419 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV60144804, COSV60147610; called by muse, mutect2, varscan2
- CCDC110 | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs775270004; called by muse, mutect2, varscan2
- CCDC136 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 140/499 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1386676803; called by muse, mutect2, varscan2
- CCDC144A | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs776838832, COSV60700753; called by muse, mutect2, varscan2
- CCDC158 | c.2636C>T p.S879L | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.285); catalogued as COSV66356848; called by muse, mutect2, varscan2
- CCDC166 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 137/590 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1554616814; called by muse, mutect2, varscan2
- CCDC168 | c.13109C>T p.P4370L | Missense Mutation (SNP) | VAF 106/448 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs778985654; called by muse, mutect2, varscan2
- CCDC168 | c.13082G>A p.G4361E | Missense Mutation (SNP) | VAF 127/428 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV59419881; called by muse, mutect2, varscan2
- CCDC171 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52652511; called by muse, mutect2, varscan2
- CCDC171 | c.3388G>A p.E1130K | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV52633332; called by muse, mutect2, varscan2
- CCDC178 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV55783290; called by muse, mutect2, varscan2
- CCDC178 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV55784333; called by muse, mutect2
- CCDC30 | c.403G>A p.E135K (on ENST00000340612; = p.E92K on NM_001080850.3) | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs12746482, COSV59608223; called by muse, mutect2, varscan2
- CCDC38 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1293079824; called by muse, mutect2, varscan2
- CCDC60 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 96/424 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs1314236733; called by muse, mutect2, varscan2
- CCDC7 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.845); catalogued as COSV100177215; called by muse, mutect2, varscan2
- CCDC88B | c.1792C>T p.L598F | Missense Mutation (SNP) | VAF 145/555 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.621); catalogued as rs555595897; called by muse, mutect2, varscan2
- CCKBR | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 140/488 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.656); catalogued as rs1451554986, COSV58104496; called by muse, mutect2, varscan2
- CCN6 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1562595135, COSV57889740; called by muse, mutect2, varscan2
- CCNA1 | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 116/466 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757758557; called by muse, mutect2, varscan2
- CCNB3 | c.1606A>T p.K536* | Nonsense Mutation (SNP) | VAF 129/500 reads (26%) | catalogued as COSV52072359; called by muse, mutect2, varscan2
- CCT8L2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 101/408 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV63463845; called by muse, mutect2, varscan2
- CCT8L2 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 98/462 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV63461779; called by muse, varscan2
- CCT8L2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 125/528 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV63463037; called by muse, mutect2, varscan2
- CD163 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 139/478 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.648); catalogued as rs745697104, COSV63129837; called by muse, mutect2, varscan2
- CD163L1 | c.2064G>A p.M688I | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as COSV58019338; called by muse, mutect2, varscan2
- CD1A | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 151/485 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1012151702, COSV99192272; called by muse, mutect2, varscan2
- CD1B | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs752275251, COSV63804991; called by muse, mutect2, varscan2
- CD2BP2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 141/437 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1261966633; called by muse, mutect2, varscan2
- CD300A | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 113/726 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60409440; called by muse, mutect2, varscan2
- CD300LB | c.441G>A p.K147= | Splice Region (SNP) | VAF 92/478 reads (19%) | catalogued as COSV58725419; called by muse, varscan2
- CD33 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as COSV51800496; called by muse, mutect2, varscan2
- CD5L | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs868295471; called by muse, mutect2, varscan2
- CD6 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 124/480 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV57837085; called by muse, mutect2, varscan2
- CDCA2 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs765231573; called by muse, mutect2, varscan2
- CDCP1 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 248/589 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150012991, COSV56108756; called by muse, mutect2, varscan2
- CDCP2 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 84/405 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as rs536040762; called by muse, mutect2, varscan2
- CDH13 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.657); catalogued as COSV99232689; called by muse, mutect2, varscan2
- CDH13 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 115/362 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV51804764; called by muse, mutect2, varscan2
- CDH20 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 136/528 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV53010155; called by muse, mutect2, varscan2
- CDH23 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs780068885; called by muse, mutect2, varscan2
- CDH23 | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1339760824, COSV99824804; called by muse, mutect2, varscan2
- CDH4 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 112/396 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs775223229; called by muse, varscan2
- CDH7 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 106/448 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59881556; called by muse, mutect2, varscan2
- CDH7 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 155/466 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as COSV59884758, COSV59897444; called by muse, mutect2, varscan2
- CDK11A | c.1262G>A p.R421Q (on ENST00000378633 / NM_001313896.2; = p.R418Q on NM_024011.4) | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1311744460; called by muse, mutect2, varscan2
- CDKAL1 | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 98/306 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as rs761883828, COSV51179707; called by muse, mutect2, varscan2
- CDKL3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 84/539 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1312304536, COSV54744714; called by muse, mutect2, varscan2
- CEACAM3 | c.627G>A p.S209= | Splice Region (SNP) | VAF 62/250 reads (25%) | catalogued as rs565000338, COSV55761179; called by muse, varscan2
- CECR2 | c.2171C>T p.P724L (on ENST00000342247 / NM_001290047.2; = p.P541L on NM_001290046.1) | Missense Mutation (SNP) | VAF 105/421 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs749506545; called by muse, mutect2, varscan2
- CELF3 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 104/326 reads (32%) | catalogued as COSV99310271; called by muse, mutect2, varscan2
- CEMIP | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 128/447 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475958112, COSV55000020; called by muse, mutect2, varscan2
- CENPE | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs758681737, COSV54381121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPP | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 56/219 reads (26%) | catalogued as rs376825324; called by muse, mutect2, varscan2
- CEP126 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 327/594 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs770830961; called by muse, mutect2, varscan2
- CEP250 | c.2473G>A p.E825K | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs1479017026; called by muse, mutect2, varscan2
- CEP350 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs770100393; called by muse, mutect2, varscan2
- CEP95 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs372545881; called by muse, mutect2, varscan2
- CES1 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1468076589, COSV100828628; called by muse, mutect2
- CFAP221 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV54654068; called by muse, mutect2, varscan2
- CFAP46 | c.3061G>A p.G1021R | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs904956906, COSV104424141; called by muse, mutect2, varscan2
- CFAP47 | c.4898C>T p.S1633L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1215627373; called by muse, mutect2, varscan2
- CFAP47 | c.7855G>A p.D2619N | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1430403763, COSV66217613; called by muse, mutect2, varscan2
- CFAP53 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267605199, COSV68351395; called by muse, mutect2, varscan2
- CFAP54 | c.5741G>A p.R1914K | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.309); catalogued as COSV61571492; called by muse, mutect2, varscan2
- CFAP61 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 105/396 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs147290599, COSV99846458; called by muse, mutect2, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CFAP69 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as COSV100290377, COSV60187649; called by muse, mutect2, varscan2
- CFAP69 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV60187690; called by muse, mutect2, varscan2
- CFAP91 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 141/368 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746475787, COSV99847277; called by muse, mutect2, varscan2
- CFAP99 | c.91G>A p.E31K (on ENST00000506607; = p.E516K on NM_001193282.3) | Missense Mutation (SNP) | VAF 85/347 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs1212578517; called by muse, mutect2, varscan2
- CFC1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 147/1082 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV52090269, COSV99383512; called by muse, mutect2, varscan2
- CFHR2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as COSV66381768; called by muse, mutect2, varscan2
- CFHR4 | c.1049C>T p.S350F (on ENST00000367416 / NM_001201551.2; = p.S104F on NM_006684.5) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs1338727661, COSV52229475, COSV99259586; called by muse, mutect2, varscan2
- CFHR5 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV56828440; called by muse, mutect2, varscan2
- CGN | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV54973395; called by muse, mutect2, varscan2
- CGNL1 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99848619; called by muse, mutect2, varscan2
- CHKB | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764209313, COSV56416128; called by muse, mutect2, varscan2
- CHM | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 94/355 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs754548037, COSV63302235, COSV63304448; called by muse, mutect2, varscan2
- CHRM3 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 88/399 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV55095146; called by muse, mutect2, varscan2
- CHRNA9 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 81/418 reads (19%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.721); catalogued as rs775085099, COSV59573670; called by muse, mutect2, varscan2
- CHRNB2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 126/625 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.108); catalogued as COSV63808433; called by muse, mutect2, varscan2
- CHST15 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 94/461 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100655381; called by muse, mutect2, varscan2
- CILK1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 95/346 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs753777674, COSV63153767; called by muse, mutect2, varscan2
- CKMT1B | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 77/364 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as rs775737368, COSV55852222; called by muse, mutect2, varscan2
- CLCA2 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 103/407 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1022166469, COSV65288885; called by muse, mutect2, varscan2
- CLCA4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760204, COSV99760826; called by muse, mutect2, varscan2
- CLCA4 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs761966713; called by muse, varscan2
- CLDN23 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 115/583 reads (20%) | catalogued as COSV67731434; called by muse, mutect2, varscan2
- CLEC19A | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 128/401 reads (32%) | catalogued as rs1218446260, COSV101513127; called by muse, mutect2, varscan2
- CLEC5A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 93/389 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69396699; called by muse, mutect2, varscan2
- CLGN | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs564584207, COSV57774139; called by muse, mutect2, varscan2
- CLIC3 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 91/487 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs758927044; called by muse, mutect2, varscan2
- CLIC6 | c.1987C>T p.P663S (on ENST00000360731 / NM_001317009.2; = p.P645S on NM_053277.3) | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62447366; called by muse, mutect2, varscan2
- CLK2 | c.526C>T p.R176* (on ENST00000368361 / NM_001294339.2; = p.R175* on NM_003993.4) | Nonsense Mutation (SNP) | VAF 80/448 reads (18%) | catalogued as rs1402327889, COSV62877336; called by muse, mutect2, varscan2
- CLSTN2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as rs983353407, COSV71720981; called by muse, mutect2, varscan2
- CLVS1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as rs779670056; called by muse, mutect2, varscan2
- CLYBL | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 96/359 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs749855204; called by muse, mutect2, varscan2
- CMYA5 | c.4036G>A p.E1346K | Missense Mutation (SNP) | VAF 160/340 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1250458266, COSV71409188; called by mutect2, varscan2
- CNGA1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.027); catalogued as COSV62057025; called by muse, mutect2, varscan2
- CNGA2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 114/442 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs149176714; called by muse, mutect2
- CNGB1 | c.3544G>A p.D1182N | Missense Mutation (SNP) | VAF 180/712 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs868226949, COSV51906019; called by muse, mutect2
- CNGB1 | c.1917G>A p.W639* | Nonsense Mutation (SNP) | VAF 85/353 reads (24%) | catalogued as rs183443649, COSV51901922, COSV99211443; called by muse, mutect2, varscan2
- CNKSR2 | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99670110; called by muse, mutect2, varscan2
- CNMD | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV100937284; called by muse, mutect2, varscan2
- CNOT1 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 66/349 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57777499; called by muse, mutect2, varscan2
- CNOT10 | c.2020C>T p.H674Y | Missense Mutation (SNP) | VAF 105/464 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV59389995; called by muse, mutect2, varscan2
- CNTLN | c.3466C>T p.R1156* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as rs199520810, COSV52083170; called by muse, mutect2, varscan2
- CNTN4 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs867810602; called by muse, mutect2, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 48/588 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, mutect2
- CNTN5 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 94/785 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs752165707, COSV54306589; called by muse, varscan2
- CNTN5 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 103/266 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as rs267603260, COSV54278153; called by muse, mutect2, varscan2
- CNTN5 | c.1129A>T p.K377* | Nonsense Mutation (SNP) | VAF 74/392 reads (19%) | catalogued as COSV99682734; called by muse, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 144/372 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, varscan2
- CNTN6 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 179/602 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs891297184; called by muse, mutect2, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, mutect2, varscan2
- CNTNAP2 | c.3275G>A p.G1092D | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.936); catalogued as rs1312151190; called by muse, mutect2, varscan2
- CNTNAP3 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1200739026; called by muse, mutect2, varscan2
- CNTNAP5 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70488656; called by muse, mutect2, varscan2
- COL11A1 | c.4786C>T p.P1596S | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62181560; called by muse, mutect2, varscan2
- COL11A2 | c.4484G>A p.G1495D (on ENST00000341947 / NM_080680.3; = p.G1388D on NM_080679.2) | Missense Mutation (SNP) | VAF 162/576 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421803975; called by muse, mutect2, varscan2
- COL11A2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 227/697 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs886100388, COSV59498686; called by muse, mutect2, varscan2
- COL12A1 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 109/386 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV59397052; called by muse, mutect2, varscan2
- COL17A1 | c.3397C>G p.R1133G | Missense Mutation (SNP) | VAF 104/341 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.268); catalogued as COSV62226680; called by muse, mutect2, varscan2
- COL18A1 | c.3803C>T p.T1268I (on ENST00000359759 / NM_130444.3; = p.T1033I on NM_030582.4) | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs1422527614, COSV100645409; called by muse, mutect2, varscan2
- COL1A1 | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 169/600 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV56802698; called by muse, mutect2, varscan2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by muse, mutect2, varscan2
- COL22A1 | c.4564C>T p.R1522C | Missense Mutation (SNP) | VAF 122/456 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as rs185123006, COSV57322173; called by muse, mutect2, varscan2
- COL27A1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1289077405; called by muse, mutect2, varscan2
- COL4A1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV65423864; called by muse, mutect2, varscan2
- COL4A1 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs368900861; called by muse, mutect2, varscan2
- COL4A3 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 98/391 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034404; called by muse, mutect2, varscan2
- COL4A3 | c.2348G>A p.G783E | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67416919; called by muse, mutect2, varscan2
- COL4A3 | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100516867; called by muse, mutect2, varscan2
- COL4A4 | c.3497G>A p.G1166E | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637147; called by muse, mutect2, varscan2
- COL4A4 | c.3019T>C p.Y1007H | Missense Mutation (SNP) | VAF 130/485 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs780331862; called by muse, mutect2, varscan2
- COL4A4 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 115/539 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771245112, COSV100307895; called by muse, mutect2, varscan2
- COL4A5 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 147/541 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60362356; called by muse, mutect2, varscan2
- COL5A1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as rs867041610; called by muse, mutect2
- COL5A2 | c.3563G>A p.G1188E | Missense Mutation (SNP) | VAF 125/428 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66416784; called by muse, mutect2, varscan2
- COL6A3 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 136/442 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs760467283, COSV55086338; called by muse, mutect2, varscan2
- COL6A5 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as rs748352703, COSV55206604; called by muse, mutect2, varscan2
- COL6A5 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591483; called by muse, mutect2, varscan2
- COL6A5 | c.3886G>A p.D1296N | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1320439803, COSV55209914; called by muse, mutect2, varscan2
- COL6A5 | c.4136G>A p.G1379E | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.473); catalogued as rs868387741, COSV55203596; called by muse, mutect2, varscan2
- COL7A1 | c.6767C>T p.P2256L | Missense Mutation (SNP) | VAF 239/584 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1160109522; called by muse, mutect2, varscan2
- COL7A1 | c.6418C>T p.R2140W | Missense Mutation (SNP) | VAF 241/549 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs766298049; called by muse, mutect2, varscan2
- COL7A1 | c.4567C>T p.P1523S | Missense Mutation (SNP) | VAF 131/543 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.863); catalogued as COSV60399854; called by muse, mutect2, varscan2
- COL7A1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 129/582 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs188978813, COSV100097729; called by muse, mutect2, varscan2
- COLEC12 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 158/578 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as COSV68374288; called by muse, mutect2, varscan2
- COMMD8 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 66/389 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.978); catalogued as rs1466358636, COSV67500322; called by muse, mutect2, varscan2
- COMTD1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs939772887, COSV53686475; called by muse, mutect2, varscan2
- CORIN | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV56691679; called by muse, mutect2, varscan2
- CORIN | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.188); catalogued as COSV56686567; called by muse, mutect2, varscan2
- CPAMD8 | c.4709C>T p.P1570L (on ENST00000651564; = p.P1523L on NM_015692.5) | Missense Mutation (SNP) | VAF 151/494 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs1217328343; called by muse, mutect2, varscan2
- CPED1 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV59997102; called by muse, mutect2, varscan2
- CPNE3 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1165259416, COSV52205584; called by muse, mutect2, varscan2
- CPS1 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99243311; called by muse, mutect2, varscan2
- CPSF4 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 112/388 reads (29%) | catalogued as rs760248771; called by muse, mutect2, varscan2
- CPXM2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944271451, COSV53860832; called by muse, mutect2, varscan2
- CR1 | c.2777G>A p.G926E | Missense Mutation (SNP) | VAF 192/555 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65464910; called by muse, mutect2, varscan2
- CR1 | c.5704C>T p.H1902Y | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.444); catalogued as COSV65458781; called by muse, mutect2, varscan2
- CR2 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1558189184; called by muse, mutect2, varscan2
- CRB2 | c.2872C>T p.R958C | Missense Mutation (SNP) | VAF 102/513 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.848); catalogued as rs1165018233; called by muse, mutect2, varscan2
- CRHR1 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs771142847; called by muse, mutect2, varscan2
- CROCC | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 116/538 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.12); catalogued as rs1257234652, COSV65010557; called by muse, mutect2, varscan2
- CRYBG1 | c.3878C>T p.P1293L | Missense Mutation (SNP) | VAF 86/411 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778938706; called by muse, mutect2, varscan2
- CRYBG1 | c.6316G>A p.D2106N | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64805741; called by muse, mutect2, varscan2
- CRYBG2 | c.3044C>T p.P1015L | Missense Mutation (SNP) | VAF 148/279 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as rs1273434665; called by muse, mutect2, varscan2
- CSHL1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 78/457 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.036); catalogued as COSV51987321; called by muse, mutect2, varscan2
- CSK | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as COSV54973752; called by muse, mutect2, varscan2
- CSMD1 | c.5791C>T p.R1931W (on ENST00000520002; = p.R1930W on NM_033225.6) | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257992819, COSV59378890; called by muse, mutect2, varscan2
- CSMD1 | c.2465C>T p.S822L (on ENST00000520002; = p.S821L on NM_033225.6) | Missense Mutation (SNP) | VAF 105/287 reads (37%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.984); catalogued as rs778158799, COSV59298685; called by muse, mutect2, varscan2
- CSMD1 | c.1223G>A p.R408Q (on ENST00000520002; = p.R407Q on NM_033225.6) | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as rs372522595, COSV68163607; called by muse, mutect2, varscan2
- CSMD2 | c.2876G>A p.G959D | Missense Mutation (SNP) | VAF 117/226 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53883842; called by muse, mutect2, varscan2
- CSMD3 | c.9958C>T p.P3320S (on ENST00000297405 / NM_001363185.1; = p.P3151S on NM_052900.3) | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV52271134; called by muse, mutect2, varscan2
- CSMD3 | c.2309C>T p.S770F (on ENST00000297405 / NM_001363185.1; = p.S666F on NM_052900.3) | Missense Mutation (SNP) | VAF 99/394 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV52229847, COSV52268030; called by muse, mutect2, varscan2
- CSPG4 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 121/457 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs775870127, COSV57891927, COSV57900762; called by muse, mutect2, varscan2
- CTAGE6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 93/490 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778979165, COSV69919016; called by muse, varscan2
- CTBP2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 202/458 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs796256730, COSV58334223; called by muse, mutect2, varscan2
- CTCF | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 72/341 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50479005; called by muse, mutect2, varscan2
- CTF1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs767711958; called by muse, mutect2, varscan2
- CTF1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 98/394 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as rs1334740549, COSV54410112; called by muse, mutect2, varscan2
- CTNNA2 | c.2591C>T p.S864L (on ENST00000402739 / NM_001282597.3; = p.S816L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448881716, COSV58151496; called by muse, mutect2, varscan2
- CTSA | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 115/370 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV51943803; called by muse, mutect2, varscan2
- CTSE | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 63/332 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV63059668; called by muse, mutect2, varscan2
- CTSS | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 140/431 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as rs868015180; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 102/529 reads (19%) | catalogued as rs764902595; called by muse, mutect2, varscan2
- CUL4B | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 104/363 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs267606335, COSV60690965; called by muse, varscan2
- CUL4B | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 118/390 reads (30%) | catalogued as CM151182, COSV60689694; called by muse, varscan2
- CWH43 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56941955; called by muse, mutect2, varscan2
- CWH43 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV56935687; called by muse, mutect2, varscan2
- CXCR3 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 154/634 reads (24%) | catalogued as COSV65461751; called by muse, mutect2, varscan2
- CXXC5 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 96/592 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.17); catalogued as rs1439260215; called by muse, mutect2, varscan2
- CXorf21 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV66762826; called by muse, mutect2, varscan2
- CYFIP2 | c.3374G>A p.R1125Q (on ENST00000616178 / NM_001291722.2; = p.R1100Q on NM_014376.4) | Missense Mutation (SNP) | VAF 224/515 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as rs745519217; called by muse, mutect2, varscan2
- CYLC1 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV61412896; called by muse, mutect2, varscan2
- CYP11A1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 84/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763187434, COSV51432742, COSV99166051; called by muse, mutect2, varscan2
- CYP11B1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 148/503 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs373856010, COSV52828175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2A6 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99991773; called by muse, mutect2, varscan2
- CYP2A7 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52502356; called by muse, varscan2
- CYP2B6 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57845439; called by muse, mutect2, varscan2
- CYP2C18 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 78/327 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1246555682, COSV53670384, COSV53671143, COSV53672129; called by muse, varscan2
- CYP2C18 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV53671862; called by muse, varscan2
- CYP2C19 | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 99/444 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as rs757537906, COSV64907665; called by muse, mutect2, varscan2
- CYP2D7 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 155/533 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs545151337, COSV63851811; called by muse, mutect2, varscan2
- CYP2D7 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 76/318 reads (24%) | catalogued as rs1472948735; called by muse, mutect2, varscan2
- CYP4A11 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100152076; called by muse, mutect2, varscan2
- CYP4F11 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 89/319 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as rs751487605, COSV56127303; called by muse, mutect2, varscan2
- CYP4F11 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV56125895; called by muse, mutect2, varscan2
- CYP4F12 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 88/352 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs749623963; called by muse, mutect2, varscan2
- CYP4F22 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as rs767066474, COSV54109771; called by muse, mutect2, varscan2
- CYRIA | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV62865079; called by muse, mutect2, varscan2
- DAB2IP | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1328209385, COSV99406790; called by muse, mutect2, varscan2
- DAO | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs775565169, COSV57321261; called by muse, mutect2, varscan2
- DAO | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 113/380 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762653262; called by muse, mutect2, varscan2
- DAO | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 89/361 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs764973777, COSV57322547; called by muse, mutect2, varscan2
- DBP | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 176/686 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.063); catalogued as rs1320737970; called by muse, mutect2, varscan2
- DBX2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 113/426 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60336883, COSV60339626; called by muse, mutect2, varscan2
- DCAF12L1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 196/736 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as rs868353872, COSV100948149, COSV64421461; called by muse, mutect2, varscan2
- DCAF8L1 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101491423; called by muse, mutect2, varscan2
- DCANP1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 272/680 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.14); catalogued as COSV72345950; called by muse, mutect2
- DCBLD1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 91/401 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV51647030; called by muse, mutect2, varscan2
- DCC | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 102/367 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs867303462; called by muse, mutect2, varscan2
- DCC | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 110/348 reads (32%) | catalogued as COSV59088081; called by muse, mutect2, varscan2
- DCC | c.3480G>A p.M1160I | Missense Mutation (SNP) | VAF 135/470 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs938589007; called by muse, mutect2, varscan2
- DCC | c.4270G>A p.D1424N | Missense Mutation (SNP) | VAF 85/375 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV71428464, COSV71432003; called by muse, mutect2, varscan2
- DCD | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.931); catalogued as rs771873825; called by muse, mutect2, varscan2
- DCDC1 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs868553033, COSV60833573; called by muse, mutect2, varscan2
- DCDC2C | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 88/336 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.039); catalogued as rs960798381; called by muse, varscan2
- DCLK3 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761277661; called by muse, mutect2, varscan2
- DCSTAMP | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 125/467 reads (27%) | catalogued as COSV99886219; called by muse, mutect2, varscan2
- DCTN4 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 116/564 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs762421082, COSV69782028; called by muse, mutect2, varscan2
- DDC | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 78/385 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63565895; called by muse, mutect2, varscan2
- DDX4 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.022); catalogued as rs137993034; called by muse, mutect2, varscan2
- DEF8 | c.685T>C p.Y229H (on ENST00000268676 / NM_207514.3; = p.Y168H on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/402 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs751583125; called by muse, mutect2, varscan2
- DEFB113 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.245); catalogued as COSV100435382; called by muse, mutect2, varscan2
- DEFB116 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 67/358 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1289195871; called by muse, mutect2, varscan2
- DEFB119 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 86/300 reads (29%) | catalogued as rs773450020, COSV99489094; called by muse, mutect2, varscan2
- DEFB128 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 74/295 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57685817; called by muse, mutect2, varscan2
- DENND5B | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 129/419 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs368956997; called by muse, mutect2, varscan2
- DGAT2L6 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 145/596 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV60718335; called by muse, mutect2, varscan2
- DGCR2 | c.1366C>T p.H456Y | Missense Mutation (SNP) | VAF 115/423 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs758583945, COSV54221368; called by muse, mutect2, varscan2
- DHCR7 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 123/517 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1449741699; called by muse, mutect2, varscan2
- DHX8 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 85/313 reads (27%) | catalogued as rs765250584; called by muse, mutect2, varscan2
- DIAPH3 | c.1343G>A p.R448Q (on ENST00000400324 / NM_001042517.2; = p.R185Q on NM_030932.3) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs145827856, COSV57369405; called by muse, mutect2, varscan2
- DIP2C | c.3887C>T p.S1296L | Missense Mutation (SNP) | VAF 89/431 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV55148602; called by muse, mutect2
- DIP2C | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 79/265 reads (30%) | catalogued as COSV55157338; called by muse, mutect2, varscan2
- DLEC1 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 214/485 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV57301020; called by muse, mutect2, varscan2
- DLG4 | c.869C>T p.S290F (on ENST00000399506 / NM_001321075.3; = p.S333F on NM_001365.4) | Missense Mutation (SNP) | VAF 125/564 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV57240311; called by muse, mutect2, varscan2
- DLGAP1 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 125/531 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1298416995, COSV59793093; called by muse, mutect2, varscan2
- DLGAP4 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 171/516 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs768625699; called by muse, mutect2, varscan2
- DMBT1 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 127/556 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1565751640, COSV57552875; called by muse, mutect2, varscan2
- DMBT1 | c.3019G>A p.E1007K (on ENST00000338354 / NM_001377530.1; = p.E508K on NM_004406.3) | Missense Mutation (SNP) | VAF 278/733 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1287582806; called by muse, mutect2, varscan2
- DMD | c.10490C>T p.S3497F | Missense Mutation (SNP) | VAF 133/515 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV58904405; called by muse, mutect2, varscan2
- DMRT3 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs748735383, COSV51904314; called by muse, mutect2
- DMRTC2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 102/438 reads (23%) | catalogued as rs141103699; called by muse, mutect2, varscan2
- DMXL2 | c.6460C>T p.L2154F | Missense Mutation (SNP) | VAF 131/431 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs769028312; called by muse, mutect2, varscan2
- DNAH10 | c.3439G>A p.E1147K (on ENST00000409039; = p.E1086K on NM_207437.3) | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV68997340; called by muse, mutect2, varscan2
- DNAH10 | c.4303G>A p.E1435K (on ENST00000409039; = p.E1374K on NM_207437.3) | Missense Mutation (SNP) | VAF 117/414 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.201); catalogued as COSV69001564; called by muse, mutect2, varscan2
- DNAH11 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100179157; called by muse, mutect2, varscan2
- DNAH11 | c.3832C>T p.P1278S | Missense Mutation (SNP) | VAF 132/307 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV60948468; called by muse, mutect2, varscan2
- DNAH11 | c.11965C>T p.Q3989* | Nonsense Mutation (SNP) | VAF 100/338 reads (30%) | catalogued as COSV100178890; called by muse, mutect2, varscan2
- DNAH11 | c.13184G>A p.R4395Q | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs368249392, COSV60954764; called by muse, mutect2, varscan2
- DNAH12 | c.2959G>A p.E987K (on ENST00000351747; = p.E1010K on NM_001366028.2) | Missense Mutation (SNP) | VAF 57/436 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV61058110; called by muse, mutect2
- DNAH14 | c.4024G>A p.E1342K (on ENST00000445597; = p.E1747K on NM_001367479.1) | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60742212; called by muse, varscan2
- DNAH14 | c.6715G>A p.E2239K (on ENST00000445597; = p.E2892K on NM_001367479.1) | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV100586859; called by muse, mutect2, varscan2
- DNAH17 | c.10471G>A p.E3491K | Missense Mutation (SNP) | VAF 178/534 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752894740, COSV67750374; called by muse, mutect2, varscan2
- DNAH17 | c.8362C>T p.R2788C | Missense Mutation (SNP) | VAF 85/485 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445952853, COSV67760553; called by muse, mutect2, varscan2
- DNAH17 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 88/522 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs745939725; called by muse, varscan2
- DNAH2 | c.12085G>A p.E4029K | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs751179381, COSV66717395; called by muse, mutect2, varscan2
- DNAH3 | c.11323C>T p.P3775S | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141308833; called by muse, mutect2, varscan2
- DNAH3 | c.9709G>A p.E3237K | Missense Mutation (SNP) | VAF 136/481 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV54512537; called by muse, mutect2, varscan2
- DNAH3 | c.5002G>A p.E1668K | Missense Mutation (SNP) | VAF 98/343 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.103); catalogued as rs762197687, COSV54548298; called by muse, mutect2, varscan2
- DNAH5 | c.13492G>A p.E4498K | Missense Mutation (SNP) | VAF 151/281 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54204981; called by muse, mutect2, varscan2
- DNAH5 | c.8849G>A p.G2950E | Missense Mutation (SNP) | VAF 198/324 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760127558, COSV54246171; called by muse, mutect2, varscan2
- DNAH5 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 125/205 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV54202095, COSV54246376; called by muse, mutect2, varscan2
- DNAH7 | c.9848C>T p.S3283F | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56765137; called by muse, mutect2, varscan2
- DNAH7 | c.6950G>A p.R2317Q | Missense Mutation (SNP) | VAF 131/468 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs1262544571, COSV56750341, COSV56756852; called by muse, mutect2, varscan2
- DNAH7 | c.4921C>T p.Q1641* | Nonsense Mutation (SNP) | VAF 83/300 reads (28%) | catalogued as COSV100416368; called by muse, mutect2, varscan2
- DNAH8 | c.3901G>A p.G1301R | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV100542716; called by muse, mutect2, varscan2
- DNAH8 | c.12301-1G>A p.X4101_splice | Splice Site (SNP) | VAF 52/232 reads (22%) | catalogued as rs761243234; called by muse, mutect2, varscan2
- DNAH9 | c.2931C>T p.V977= | Splice Region (SNP) | VAF 50/272 reads (18%) | catalogued as rs1337463867, COSV52367451; called by muse, mutect2
- DNAH9 | c.8083G>A p.E2695K | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV52347429; called by muse, mutect2, varscan2
- DNAH9 | c.10993G>A p.E3665K | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs1455394522; called by muse, mutect2, varscan2
- DNAI1 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 49/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54281245; called by muse, mutect2, varscan2
- DNAJB1 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748971999; called by muse, mutect2, varscan2
- DNAJC14 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 100/374 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV57913619; called by muse, mutect2, varscan2
- DNAJC5B | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs267601967, COSV52536926; called by muse, mutect2, varscan2
- DNTT | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs267602650; called by muse, mutect2, varscan2
- DOCK3 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56546332; called by muse, varscan2
- DOCK3 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 104/464 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs368447292; called by muse, varscan2
- DOCK3 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 166/406 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs267599882, COSV99814878; called by muse, varscan2
- DOCK3 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 236/556 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56554929; called by muse, varscan2
- DOK7 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 165/578 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs773273397; called by muse, mutect2, varscan2
- DPPA3 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 107/362 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs370250392; called by muse, mutect2, varscan2
- DPY19L1 | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs1309946271; called by muse, mutect2, varscan2
- DPYD | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV64593381; called by muse, mutect2, varscan2
- DPYD | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 227/416 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64594585; called by muse, mutect2, varscan2
- DPYS | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 110/392 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV60906546; called by muse, mutect2, varscan2
- DQX1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 182/528 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139246314; called by muse, mutect2, varscan2
- DRC1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV56530754; called by muse, mutect2, varscan2
- DRD5 | c.680T>C p.I227T | Missense Mutation (SNP) | VAF 76/384 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs935559976; called by muse, mutect2, varscan2
- DRD5 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 82/385 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs867960497, COSV58578378; called by muse, mutect2, varscan2
- DSC2 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 146/457 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV51864962; called by muse, mutect2, varscan2
- DSCAM | c.6002G>A p.G2001E | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as COSV68019987; called by muse, mutect2, varscan2
- DSCAM | c.5579C>T p.S1860F | Missense Mutation (SNP) | VAF 88/445 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1473252916, COSV101260350; called by muse, mutect2, varscan2
- DSCAM | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 105/496 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.146); catalogued as rs957826009, COSV68032890; called by muse, mutect2, varscan2
- DSCAM | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.087); catalogued as COSV68650332; called by muse, mutect2, varscan2
- DSG1 | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 148/413 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs372724391, COSV99935466; called by muse, mutect2, varscan2
- DSG3 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57128431; called by muse, varscan2
- DSG4 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57394227; called by muse, varscan2
- DSG4 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV57394759; called by muse, mutect2, varscan2
- DSP | c.6079G>A p.E2027K | Missense Mutation (SNP) | VAF 149/486 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs762538310, COSV65792113; called by muse, mutect2, varscan2
- DSPP | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 213/644 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1441961526, COSV99217676; called by muse, mutect2, varscan2
- DST | c.22033C>A p.P7345T (on ENST00000361203 / NM_001374722.1; = p.P5055T on NM_015548.5) | Missense Mutation (SNP) | VAF 124/340 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1298948196; called by muse, mutect2
- DST | c.22031T>C p.L7344P (on ENST00000361203 / NM_001374722.1; = p.L5054P on NM_015548.5) | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as COSV55033079; called by muse, mutect2
- DUS2 | c.420C>T p.I140= | Splice Region (SNP) | VAF 41/243 reads (17%) | catalogued as COSV62708226; called by muse, mutect2, varscan2
- DYNC1H1 | c.4531C>A p.P1511T | Missense Mutation (SNP) | VAF 90/361 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64140470; called by muse, mutect2, varscan2
- DYNC1H1 | c.11998C>T p.R4000C | Missense Mutation (SNP) | VAF 104/457 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1407764077; called by muse, mutect2, varscan2
- DYNC1I1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 111/404 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.984); catalogued as COSV61463209; called by muse, mutect2, varscan2
- DYNC2H1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 263/432 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1167239013; called by muse, mutect2, varscan2
- DYSF | c.5173G>A p.D1725N | Missense Mutation (SNP) | VAF 115/361 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs912484170, COSV50513184; called by muse, mutect2, varscan2
- EAF2 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 127/280 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs868144591; called by muse, mutect2, varscan2
- EBF1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 178/428 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100565902; called by muse, mutect2, varscan2
- ECEL1 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 140/494 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1354090491, COSV100458502, COSV58813025; called by muse, mutect2, varscan2
- EDA2R | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 158/613 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs368988128, COSV53630365; called by muse, mutect2, varscan2
- EDAR | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs868037570, COSV51506119; called by muse, mutect2, varscan2
- EDDM3B | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 110/422 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV100460822; called by muse, mutect2, varscan2
- EDN3 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 101/436 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1452307925; called by muse, varscan2
- EFCAB13 | c.1880C>T p.S627F | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs749417952, COSV58945719; called by muse, mutect2, varscan2
- EFHB | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 260/656 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as COSV55545742; called by muse, mutect2, varscan2
- EFNB3 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 98/328 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs775401545; called by muse, mutect2, varscan2
- EFR3A | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs1321002901; called by muse, mutect2, varscan2
- EGFR | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs559717059, CM164464, COSV51776282; called by muse, mutect2, varscan2
- EIF2B4 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754958652, COSV52007679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELANE | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 150/549 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764500411; called by muse, mutect2, varscan2
- ELAPOR1 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64040366; called by muse, mutect2, varscan2
- ELMO1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 130/317 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV60324258; called by muse, mutect2, varscan2
- ELMO1 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 169/409 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1447676557, COSV60297074; called by muse, mutect2, varscan2
- ELMO2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 112/414 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs775922880, COSV51683376; called by muse, mutect2, varscan2
- ELOA2 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 93/373 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55295225; called by muse, mutect2, varscan2
- ELOVL3 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.066); catalogued as rs140986921, COSV64174253; called by muse, mutect2, varscan2
- ELOVL4 | c.119G>A p.W40* | Nonsense Mutation (SNP) | VAF 66/287 reads (23%) | catalogued as COSV100876115; called by muse, mutect2, varscan2
- EMILIN3 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 144/548 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777095908; called by muse, mutect2, varscan2
- EML5 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.354); catalogued as rs761519632; called by muse, mutect2, varscan2
- ENG | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 98/316 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61228011; called by muse, mutect2, varscan2
- ENGASE | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 131/768 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs548438605; called by muse, mutect2, varscan2
- ENPP2 | c.1597C>T p.H533Y (on ENST00000075322 / NM_001040092.3; = p.H585Y on NM_006209.5) | Missense Mutation (SNP) | VAF 109/391 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs200876689; called by muse, mutect2, varscan2
- ENPP6 | c.534G>A p.K178= | Splice Region (SNP) | VAF 98/305 reads (32%) | catalogued as rs1288558303, COSV99698752; called by muse, varscan2
- EOLA2 | c.387G>A p.W129* | Nonsense Mutation (SNP) | VAF 136/518 reads (26%) | catalogued as rs782786659; called by muse, mutect2, varscan2
- EP300 | c.2863C>T p.P955S | Missense Mutation (SNP) | VAF 106/367 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as COSV54331382; called by muse, mutect2, varscan2
- EPHA3 | c.1898G>A p.G633E | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60708188, COSV99072105; called by muse, mutect2, varscan2
- EPHA4 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 124/514 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56036231; called by muse, mutect2, varscan2
- EPHA6 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 79/382 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs760704852, COSV67556568; called by muse, mutect2, varscan2
- EPHA6 | c.2362C>T p.R788C (on ENST00000389672 / NM_001080448.3; = p.R180C on NM_173655.4) | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771887549, COSV101060621; called by muse, mutect2, varscan2
- EPHA6 | c.2573G>A p.R858Q (on ENST00000389672 / NM_001080448.3; = p.R250Q on NM_173655.4) | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs776617495, COSV67571163; called by muse, mutect2, varscan2
- EPHA7 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 95/341 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867402067, COSV65179212; called by muse, mutect2, varscan2
- EPHA7 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1256527658, COSV65191152, COSV65194854; called by muse, mutect2, varscan2
- EPHA8 | c.1901G>A p.R634K | Missense Mutation (SNP) | VAF 177/364 reads (49%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.966); catalogued as COSV51278691; called by muse, mutect2, varscan2
- EPHB1 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 143/414 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV101212900, COSV67662807, COSV67667023; called by muse, mutect2, varscan2
- EPHB1 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1171028779, COSV101213147, COSV67673952; called by muse, mutect2, varscan2
- EPHB2 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 140/478 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs551164855; called by muse, varscan2
- EPHB2 | c.2822C>T p.S941F (on ENST00000400191 / NM_001309193.2; = p.S942F on NM_004442.7) | Missense Mutation (SNP) | VAF 83/357 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65863276; called by muse, mutect2, varscan2
- EPN2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 121/461 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59060167; called by muse, mutect2, varscan2
- EPPK1 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 117/492 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs182592273; called by muse, mutect2, varscan2
- EPX | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 84/501 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56598441; called by muse, mutect2, varscan2
- ERBB4 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 110/385 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs748447524, COSV99627996, COSV99633316; called by muse, mutect2, varscan2
- ERG | c.1256C>T p.P419L (on ENST00000398919 / NM_001243428.1; = p.P395L on NM_004449.4) | Missense Mutation (SNP) | VAF 137/453 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV55727766; called by muse, mutect2, varscan2
- ERICH3 | c.3788G>A p.G1263E | Missense Mutation (SNP) | VAF 149/477 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs750554479; called by muse, mutect2, varscan2
- ERVV-1 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 60/393 reads (15%) | catalogued as rs1317382956; called by muse, varscan2
- ESM1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 177/345 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs867242618; called by muse, mutect2, varscan2
- ESRP2 | c.1202C>T p.P401L (on ENST00000565858 / NM_001365264.1; = p.P391L on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/543 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1447308697; called by muse, mutect2, varscan2
- ETNK1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465224773, COSV56888211; called by muse, mutect2, varscan2
- ETV7 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60316806; called by muse, mutect2, varscan2
- EVC | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 118/376 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV53830136; called by muse, mutect2, varscan2
- EVPL | c.6023T>C p.L2008P | Missense Mutation (SNP) | VAF 102/665 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113288371; called by muse, varscan2
- EVPL | c.5438C>T p.S1813F | Missense Mutation (SNP) | VAF 126/798 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as rs373617823, COSV56907693; called by muse, mutect2, varscan2
- EVPL | c.4141G>A p.D1381N | Missense Mutation (SNP) | VAF 140/793 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV56913215; called by muse, varscan2
- EVPL | c.3386C>T p.S1129L | Missense Mutation (SNP) | VAF 133/723 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs757898505; called by muse, mutect2, varscan2
- EVPL | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 138/895 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs530566450, COSV101648818; called by muse, mutect2, varscan2
- EVPL | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 158/860 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs750569215; called by muse, mutect2, varscan2
- EXD3 | c.1933C>T p.L645F | Missense Mutation (SNP) | VAF 132/414 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59809220; called by muse, mutect2, varscan2
- EXOC2 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 119/320 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100033885; called by muse, mutect2, varscan2
- EXOC6 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 62/216 reads (29%) | catalogued as rs749349414, COSV53323272; called by muse, mutect2, varscan2
- EXOC6B | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 82/305 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs866488817; called by muse, varscan2
- EXT1 | c.1714A>G p.T572A | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as CD099322; called by muse, mutect2, varscan2
- EXTL2 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100921096; called by muse, mutect2, varscan2
- EYA1 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as CM081602, COSV58163151; called by muse, mutect2, varscan2
- EZH1 | c.1925A>T p.Y642F | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV70550424; called by muse, mutect2, varscan2
- F12 | c.57G>A p.S19= | Splice Region (SNP) | VAF 57/324 reads (18%) | catalogued as rs1381011986; called by muse, mutect2, varscan2
- F13B | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 104/344 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.069); catalogued as rs376931227; called by muse, mutect2, varscan2
- F13B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.038); catalogued as COSV66374522; called by muse, varscan2
- F13B | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV66374688; called by muse, varscan2
- F5 | c.2444G>A p.G815D | Missense Mutation (SNP) | VAF 134/414 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs372031263; called by muse, mutect2
- F5 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV63122667; called by muse, mutect2, varscan2
- FA2H | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 96/440 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as rs769477853; called by muse, mutect2, varscan2
- FAAH2 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766737067, COSV66504673; called by muse, mutect2, varscan2
- FAM110C | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 215/671 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs936645843; called by muse, mutect2, varscan2
- FAM117B | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 61/263 reads (23%) | catalogued as rs61740247, COSV57422501; called by muse, mutect2, varscan2
- FAM117B | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 151/518 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs770032345, COSV100287322; called by muse, mutect2, varscan2
- FAM120C | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 157/573 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV60262474; called by muse, mutect2, varscan2
- FAM155B | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1239621030, COSV52936348; called by muse, mutect2, varscan2
- FAM170A | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 176/344 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.801); catalogued as COSV58927658, COSV58927824; called by muse, mutect2, varscan2
- FAM170A | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 183/406 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs1016030996, COSV58927380; called by muse, mutect2, varscan2
- FAM171A2 | c.1780G>A p.G594S | Missense Mutation (SNP) | VAF 130/437 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as rs1346940476; called by muse, mutect2, varscan2
- FAM184B | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs971918248; called by muse, mutect2, varscan2
- FAM209B | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 67/347 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs1445616916, COSV64914975; called by muse, mutect2, varscan2
- FAM240B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.807); catalogued as COSV61821273; called by muse, mutect2, varscan2
- FAM47B | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 93/396 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.986); catalogued as rs758648172, COSV61452399; called by muse, mutect2, varscan2
- FAM47B | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 158/519 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV61454558; called by muse, mutect2, varscan2
- FAM47B | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 117/437 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs749071026; called by muse, mutect2, varscan2
- FAM47C | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 182/715 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as rs782700992, COSV100792905, COSV63729110; called by muse, mutect2, varscan2
- FAM71B | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 270/649 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); catalogued as COSV57228773; called by muse, mutect2, varscan2
- FAM83B | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 114/426 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV60923235; called by muse, mutect2, varscan2
- FAM83B | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 99/394 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as rs776649451, COSV60922779; called by muse, mutect2, varscan2
- FAM83C | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 133/599 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs761920367, COSV65582064; called by muse, mutect2, varscan2
- FAM83E | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 83/331 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367823673; called by muse, mutect2, varscan2
- FAM90A1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 84/341 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.34); catalogued as rs780112980, COSV100274146; called by muse, varscan2
- FANK1 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs777933185; called by muse, mutect2, varscan2
- FASTKD5 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 112/410 reads (27%) | catalogued as COSV53906327; called by muse, mutect2, varscan2
6,542 further variants in this file (3,951 protein-altering or splice-affecting, 2,330 silent, 261 other) are not listed here.
